Somatic mutation profile of tumor specimen TCGA-DX-AB35-01A (aliquot TCGA-DX-AB35-01A-21D-A417-09) from TCGA case TCGA-DX-AB35, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Descending colon; Age at diagnosis: 65.8 years (24,026 days).
Specimen TCGA-DX-AB35-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5b2dfff-849d-4d8b-848e-b2899fab7b6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB35-11A (Solid Tissue Normal), aliquot TCGA-DX-AB35-11A-11D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e4cd337-7b0f-4594-97b4-9910d166d3c8

The open-access MAF lists 36 somatic variants for this specimen: 33 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 32, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.11623G>T p.G3875W | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101447156; called by muse, mutect2
- C1QA | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs201517118, COSV101009528; called by muse, mutect2
- CALD1 | c.1731G>T p.K577N (on ENST00000361675 / NM_033138.4; = p.K322N on NM_004342.7) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs773589171, COSV100724510; called by muse, mutect2, varscan2
- CALN1 | c.551A>G p.N184S (on ENST00000329008 / NM_001017440.3; = p.N226S on NM_031468.4) | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.85); PolyPhen benign (0.131); catalogued as COSV100208751; called by muse, mutect2, varscan2
- CEP43 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV100835722; called by muse, mutect2, varscan2
- CYP27B1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 94/383 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.481); catalogued as rs1471238106, COSV99141633; called by muse, mutect2, varscan2
- DNAH17 | c.13316C>T p.T4439I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771797237, COSV99428472; called by muse, mutect2, varscan2
- DOCK3 | c.2222G>A p.R741Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs778009798, COSV56529714, COSV99812979; called by muse, mutect2, varscan2
- DUSP22 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266399615, COSV100740019, COSV60525748; called by muse, mutect2, varscan2
- ERICH3 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.719); catalogued as COSV100445363, COSV58606106; called by muse, varscan2
- FAM53B | c.1254G>T p.Q418H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100484239; called by muse, mutect2, varscan2
- FOXK2 | c.847G>T p.G283W | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100082373, COSV58876983; called by muse, mutect2
- FRS2 | c.410C>G p.T137R | Missense Mutation (SNP) | VAF 42/1512 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.1); catalogued as COSV100166312; called by muse, mutect2
- HELLS | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs752164311, COSV99492306; called by muse, mutect2, varscan2
- HTR1A | c.252G>T p.M84I | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV100109237; called by muse, mutect2, varscan2
- KCNJ3 | c.494A>T p.Q165L | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99716340; called by muse, mutect2, varscan2
- KRR1 | c.666A>C p.L222F | Missense Mutation (SNP) | VAF 57/429 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56990080; called by muse, mutect2, varscan2
- LRRK1 | c.4978G>T p.G1660C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99442462; called by muse, mutect2
- MBD6 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as COSV100851794; called by muse, mutect2, varscan2
- MMUT | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV99222533; called by muse, mutect2, varscan2
- NEXMIF | c.3190C>T p.R1064C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195044913, COSV50032739; called by muse, mutect2, varscan2
- PTPRB | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 129/304 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV100547838; called by muse, mutect2, varscan2
- RCL1 | c.1046A>T p.E349V | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV101099436; called by muse, mutect2, varscan2
- RELB | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.733); catalogued as rs55723886, COSV55508191; called by muse, mutect2, varscan2
- RYR3 | c.1196G>T p.R399I | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101213985, COSV66782640; called by muse, mutect2
- RYR3 | c.4126G>A p.G1376S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101213988; called by muse, mutect2, varscan2
- SHPRH | c.2102T>C p.F701S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99262590; called by muse, mutect2, varscan2
- SPATA31D1 | c.3536C>T p.S1179F | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV100783009; called by muse, mutect2, varscan2
- SPEG | c.7622G>A p.S2541N | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as COSV100405399; called by muse, mutect2, varscan2
- UTP18 | c.1101G>T p.L367F | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV99834918; called by muse, mutect2
- WDSUB1 | c.953-1G>A p.X318_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100701890; called by muse, mutect2, varscan2
- ZNF792 | c.795C>A p.N265K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV101289745; called by muse, mutect2
- ZZZ3 | c.2090G>A p.S697N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100890425; called by muse, mutect2, varscan2
- CALCOCO1 | c.300C>T p.F100= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs772966574, COSV50421851; called by muse, mutect2, varscan2
- HYDIN | c.8259G>A p.T2753= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs755781367, COSV99993514; called by muse, mutect2, varscan2
- OR1F1 | c.450G>T p.V150= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs773419546, COSV58961115; called by muse, mutect2, varscan2
